Somatic mutation profile of tumor specimen TARGET-20-PANTNA-04A (aliquot TARGET-20-PANTNA-04A-01D) from TARGET case TARGET-20-PANTNA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.6 years (6,416 days).
Specimen TARGET-20-PANTNA-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 918312f7-873d-43ff-8092-b724beffc63e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANTNA-14A (Bone Marrow Normal), aliquot TARGET-20-PANTNA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b04213f-8e56-4657-9e2b-513e9c9aa991

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.4081A>G p.K1361E | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as COSV64874180; called by muse, mutect2, varscan2
- BSN | c.11508G>A p.P3836= | Splice Region (SNP) | VAF 18/48 reads (38%) | catalogued as rs746620641, COSV56528347; called by muse, mutect2, varscan2
- CNTN5 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.281); catalogued as rs201259702; called by muse, mutect2
